Gene-level copy-number profile of tumor specimen TCGA-38-4631-01A from TCGA case TCGA-38-4631, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 72.7 years (26,538 days).
Specimen TCGA-38-4631-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.ed56fd85-f1e6-4144-80e1-50fbaf29f4e3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-38-4631-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/948a20fc-4b47-4b6f-9eca-d2fe14a2d5ff

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 418; copy number 3: 7,893; copy number 4: 12,757; copy number 5: 12,109; copy number 6: 13,353; copy number 7: 9,065; copy number 8: 2,197; copy number 9: 579; copy number 10: 18; copy number 11: 443; copy number 12: 416; copy number 13: 84; copy number 15: 35; copy number 16: 128; copy number 17: 59; copy number 19: 21; copy number 20: 57; copy number 23: 2; copy number 24: 23; copy number 28: 17; copy number 29: 22; copy number 34: 14; copy number 37: 57; copy number 43: 9; copy number 51: 1; copy number 78: 34.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-38-4631-01A-01D-1752-01): tumor purity 0.49, ploidy 3.1, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,004 genes in 30 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:119,821,321–125,595,497, 114 genes, copy number 12–17 (within-gene range 8–17) (broad region; genes not listed).
- chr3:126,103,562–126,197,994, 1 gene, copy number 12 (within-gene range 7–12): ALDH1L1.
- chr3:126,160,283–127,390,670, 31 genes, copy number 12 (within-gene range 8–12): RNU1-30P, ALDH1L1-AS2, AC079848.2, AC016924.1, AC063919.1, AC063919.2, KLF15, CCDC37-DT, CFAP100, AC073439.1, ZXDC, UROC1, CHST13, C3orf22, RNA5SP138, TXNRD3, AC024558.1, NUP210P1, AC078867.1, CHCHD6, RCC2P4, AC011199.1, PLXNA1, AC112482.2, C3orf56, Y_RNA, AC112482.1, RNU6-1047P, AC133681.1, PRR20G, LINC02016.
- chr3:130,212,823–132,874,223, 42 genes, copy number 12: COL6A4P2, AC093004.1, COL6A5, COL6A6, PIK3R4, RN7SKP212, AC097105.1, GSTO3P, ATP2C1, AC055733.4, AC055733.2, Y_RNA, AC055733.1, AC055733.3, ASTE1, NEK11, AC116424.1, RNU6-726P, AC010210.1, NUDT16P1, NUDT16, AC107027.3, MRPL3, SNORA58, AC107027.1, BCL2L12P1, CPNE4, AC107027.2, MIR5704, PSMC2P1, RPL7P16, ACP3, AC020633.1, NIP7P2, DNAJC13, ACAD11, NPHP3-ACAD11, ACKR4, HSPA8P19, UBA5, NPHP3, NPHP3-AS1.
- chr3:135,925,891–136,752,403, 12 genes, copy number 13 (within-gene range 8–13): AC092989.1, NDUFS6P1, PPP2R3A, AC072039.1, AC072039.2, MSL2, TDGF1P6, AC092991.1, PCCB, STAG1, RNU6-1284P, HMGN1P10.
- chr3:195,561,215–195,990,318, 22 genes, copy number 12: AC069213.2, APOD, MUC20P1, AC233280.36, AC233280.2, AC233280.1, MUC20-OT1, SDHAP2, MIR570, SMBD1P, MUC20, MUC4, LINC01983, KIF3AP1, TNK2, MIR6829, AC124944.3, TNK2-AS1, AC124944.2, RNU2-11P, AC124944.1, SDHAP1.
- chr4:55,427,903–56,710,614, 32 genes, copy number 9–13 (within-gene range 5–13): CLOCK, Y_RNA, RN7SKP30, AC024243.1, PDCL2, NMU, RNU6-276P, EXOC1L, EXOC1, RNU6-652P, AC110611.1, AC110611.2, CEP135, CRACD, RNA5SP161, RNU6-197P, AC022267.1, MRPL22P1, AASDH, RPL7AP31, AC068620.1, PPAT, AC068620.2, AC068620.3, PAICS, SRP72, ARL9, THEGL, GLDCP1, HOPX, AC108215.1, RPL17P20.
- chr5:58,198–2,262,023, 79 genes, copy number 9 (broad region; genes not listed).
- chr5:31,053,565–31,329,146, 5 genes, copy number 9 (within-gene range 6–9): RPL19P11, AC026421.1, AC113386.1, CDH6, DUX4L51.
- chr5:42,423,439–42,721,878, 1 gene, copy number 9 (within-gene range 6–9): GHR.
- chr5:42,729,138–45,098,647, 53 genes, copy number 9: AC113368.1, CCDC152, SELENOP, AC008945.1, AC008945.2, PPIAP77, PRELID3BP4, PRELID3BP5, PRELID3BP6, PRELID3BP7, AC008875.3, AC008875.2, AC008875.1, AC025171.1, AC025171.3, AC025171.5, ANXA2R, AC025171.2, AC025171.4, ZNF131, AC106800.3, NIM1K, AC106800.1, AC106800.2, TUBAP14, HMGCS1, AC114947.2, AC114947.1, CCL28, TMEM267, AC114956.2, C5orf34, EEF1A1P19, C5orf34-AS1, AC114956.1, PAIP1, NNT-AS1, AC010435.1, AMD1P3, NNT, RPL29P12, AC104119.1, RNU6-381P, FGF10, FGF10-AS1, LINC02224, AC093292.1, RN7SL383P, MRPS30-DT, AC093297.1, MRPS30, AC093297.2, AC114954.1.
- chr6:30,541,377–30,792,250, 23 genes, copy number 24 (within-gene range 4–24): GNL1, PRR3, ABCF1, MIR877, PPP1R10, MRPS18B, ATAT1, PTMAP1, C6orf136, DHX16, PPP1R18, NRM, RPL7P4, MDC1, MDC1-AS1, TUBB, AL662797.1, FLOT1, Y_RNA, IER3-AS1, IER3, HCG20, RN7SL353P.
- chr7:94,695,027–110,534,757, 378 genes, copy number 11–43 (broad region; genes not listed).
- chr7:110,662,644–111,562,517, 3 genes, copy number 23–51 (within-gene range 6–51): IMMP2L, AC073326.1, LRRN3.
- chr7:115,503,367–120,752,514, 71 genes, copy number 19–78 (broad region; genes not listed).
- chr7:127,652,194–131,110,176, 125 genes, copy number 11 (within-gene range 8–11) (broad region; genes not listed).
- chr7:145,583,197–148,420,998, 14 genes, copy number 9–12 (within-gene range 6–12): DPY19L4P2, AC006007.1, AC073308.1, CNTNAP2, AC073418.1, Y_RNA, CNTNAP2-AS1, DUTP3, RANP2, MIR548F4, AC005518.1, AC005518.2, RNU6-1184P, RNA5SP249.
- chr10:22,162,992–23,586,224, 36 genes, copy number 9: ADIPOR1P1, AL157831.1, EBLN1, AL157831.2, PSME2P6, AL157831.3, AL158211.5, AL158211.1, RPL31P45, COMMD3, COMMD3-BMI1, BMI1, AL158211.4, AL158211.2, AL158211.3, SPAG6, AL513128.1, AL513128.3, AL513128.2, PIP4K2A, AL390318.1, RNU6-413P, ARMC3, AL139815.1, RNA5SP304, MSRB2, YWHAZP3, AL139281.2, PTF1A, C10orf67, AL139281.1, AL606469.1, AL606469.2, OTUD1, AL512603.2, AL512603.1.
- chr11:43,556,436–43,673,393, 1 gene, copy number 9 (within-gene range 7–9): AC068205.1.
- chr11:43,578,889–46,121,454, 61 genes, copy number 9–15 (within-gene range 6–15) (broad region; genes not listed).
- chr13:32,303,699–56,885,602, 412 genes, copy number 9–17 (broad region; genes not listed).
- chr16:7,726,841–8,357,860, 5 genes, copy number 10 (within-gene range 6–10): AC005774.1, AC093515.1, AC018767.2, LINC02152, AC018767.3.
- chr17:26,989,189–29,057,216, 129 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr20:87,250–359,660, 13 genes, copy number 10: DEFB125, DEFB126, DEFB127, DEFB128, DEFB129, DEFB132, AL034548.1, C20orf96, ZCCHC3, AL034548.2, NRSN2-AS1, SOX12, NRSN2.
- chr20:31,303,212–33,994,357, 104 genes, copy number 12 (broad region; genes not listed).
- chr20:34,014,969–34,017,749, 1 gene, copy number 12: AL031668.1.
- chr20:46,689,659–46,864,104, 4 genes, copy number 11: AL031055.1, SLC2A10, RN7SKP33, AL354766.1.
- chr20:46,901,143–46,901,726, 1 gene, copy number 11: AL354766.2.
- chr20:53,255,979–59,847,711, 125 genes, copy number 11 (within-gene range 6–11) (broad region; genes not listed).
- chr22:19,756,703–21,517,533, 106 genes, copy number 20–37 (within-gene range 20–64) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
